CCDI case PBBHUB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/461a1186-6e20-4176-a4b3-982d9ee66bad

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (411 days).

Biospecimens (3 samples)
- Sample 0D8Y4P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D8Y4Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D8Y4X: Tissue type: Tumor; Specimen type: Solid Tissue.
